Gene-level copy-number profile of tumor specimen TCGA-DU-8167-01A from TCGA case TCGA-DU-8167, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 69.2 years (25,262 days).
Specimen TCGA-DU-8167-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.4dfcb8c5-ff3f-4eab-a1a0-8a86a467e949.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DU-8167-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 352 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1f11497b-3b16-4d6d-9f96-29bc5445635e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,356; copy number 1: 8,840; copy number 2: 48,114; copy number 3: 612; copy number 4: 190; copy number 5: 159.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DU-8167-01A-11D-2252-01): tumor purity 0.49, ploidy 3.87, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 993 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:222,199,887–242,160,153, 415 genes (broad region; genes not listed).
- chr5:178,840,097–178,841,134, 1 gene: AC126915.1.
- chr11:167,784–14,872,044, 575 genes (within-gene range 0–2) (broad region; genes not listed).
- chr17:41,265,339–41,271,835, 2 genes (within-gene range 0–2): KRTAP9-6, KRTAP9-11P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 159 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:120,380,761–127,419,050, 116 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:129,832,301–133,326,404, 43 genes, copy number 5: AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1, AC090987.1, ADCY8, AC103726.1, AC103726.2, AC087341.1, AC104257.1, SNORA72, AC060788.1, EFR3A, OC90, AC100868.1, HHLA1, KCNQ3, HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1.

Autosomal genes at a single copy (total copy number 1): 7,412. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
